EXCEPTIONAL_RESPONDERS case ER-B0GJ — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ec334574-2085-4ff4-88b3-bc3ee4657427

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1953; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 58.0 years (21,193 days); Year of diagnosis: 2011; Prior malignancy: no; Days to last follow up: 2,059 days (5.6 years); Days to best overall response: 1,451 days (4.0 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 1,107 days (3.0 years); Days to treatment end: 1,118 days (3.1 years).
   Treatment given: Therapeutic agents: Vinorelbine Tartrate; Days to treatment start: 1,119 days (3.1 years); Days to treatment end: 1,329 days (3.6 years).

Follow-up (1 entry)
- Days to follow up: 2,059 days (5.6 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,080 days (3.0 years); Days progression-free: 2,059 days (5.6 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B0GJ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B0GJ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 15; Percent tumor nuclei: 20; Percent normal cells: 70; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
